Somatic mutation profile of tumor specimen 0DD53L from CCDI case PBBNBV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,746 days).
Specimen 0DD53L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c54face-df67-456e-ac3c-038be8417111.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD53H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21fb29e9-4569-4e78-895f-20ef57c00c20

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEK4 | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 148/337 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- XPO7 | c.2935A>T p.I979F | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR36 | c.1248A>T p.T416= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- SHC3 | c.768C>T p.A256= | Silent (SNP) | VAF 13/252 reads (5%) | called by muse, mutect2
- TNRC18 | c.7698C>T p.G2566= | Silent (SNP) | VAF 63/117 reads (54%) | called by muse, mutect2, varscan2
- NR5A2 | c.321+28dup | Intron (INS) | VAF 51/321 reads (16%) | called by mutect2, pindel, varscan2
- RPL23A | c.456+76T>C | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
